Somatic mutation profile of tumor specimen TARGET-20-PATIDY-09A (aliquot TARGET-20-PATIDY-09A-01D) from TARGET case TARGET-20-PATIDY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,123 days).
Specimen TARGET-20-PATIDY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1457b159-a61d-4294-93e8-26ed4908c7b9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATIDY-14A (Bone Marrow Normal), aliquot TARGET-20-PATIDY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa215b8e-2a6c-4239-8e82-9dc0620b6e08

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs397507501, CM021125, COSV61008667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BSN | c.10569C>T p.P3523= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs536513492, COSV56513447; called by muse, mutect2, varscan2
- FGFR1 | c.1285-36C>T | Intron (SNP) | VAF 15/122 reads (12%) | catalogued as rs756501869; called by muse, mutect2, varscan2
